Somatic mutation profile of tumor specimen ALCH-B29R-TTR1-A (aliquot ALCH-B29R-TTR1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B29R, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 54.4 years (19,852 days).
Specimen ALCH-B29R-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cb0d25f2-7ca9-49ad-98cb-0181d0ddcae2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B29R-NB1-A (Blood Derived Normal), aliquot ALCH-B29R-NB1-A-1-0-D-A76N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5867d007-7690-45ce-a5b6-d2679397a39c

The open-access MAF lists 582 somatic variants for this specimen: 393 protein-altering or splice-affecting, 121 silent, 68 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 335, Silent 121, Intron 29, Nonsense Mutation 23, Frame Shift Del 14, 5'UTR 13, 3'UTR 11, RNA 11, Splice Region 9, Splice Site 5, Frame Shift Ins 5, 5'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>T p.R248L | Missense Mutation (SNP) | VAF 282/546 reads (52%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- TP53 | c.313G>T p.G105C | Missense Mutation (SNP) | VAF 79/243 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM043949, COSV52726068, COSV52741717, COSV53015551; called by muse, mutect2, varscan2
- ADAMTS20 | c.3841C>A p.L1281I | Missense Mutation (SNP) | VAF 168/420 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV101166145; called by muse, mutect2, varscan2
- AMPD1 | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 263/465 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1290122973; called by muse, mutect2, varscan2
- ANTXRL | c.1362C>A p.H454Q | Missense Mutation (SNP) | VAF 197/464 reads (42%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.994); catalogued as rs1406609183; called by muse, mutect2, varscan2
- ASCC3 | c.4878G>C p.R1626S | Missense Mutation (SNP) | VAF 118/300 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.241); catalogued as COSV64972273; called by muse, mutect2, varscan2
- ASPHD1 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 162/187 reads (87%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV58102552; called by muse, mutect2, varscan2
- ASXL3 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 178/629 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.309); catalogued as rs760550092; called by muse, mutect2, varscan2
- ATL1 | c.37G>A p.G13R | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.346); catalogued as rs1566722874; called by muse, mutect2, varscan2
- ATP2B3 | c.2876C>A p.A959E | Missense Mutation (SNP) | VAF 186/464 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.247); catalogued as COSV54845320, COSV54846951; called by muse, mutect2, varscan2
- ATR | c.5568G>T p.M1856I | Missense Mutation (SNP) | VAF 103/251 reads (41%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.705); catalogued as COSV100638592; called by muse, mutect2, varscan2
- C6orf118 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 133/217 reads (61%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs748193483, COSV57817067; called by muse, mutect2, varscan2
- CARNMT1 | c.1092A>G p.I364M | Missense Mutation (SNP) | VAF 100/124 reads (81%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100961634; called by muse, mutect2, varscan2
- CBX4 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 213/354 reads (60%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as COSV53965248; called by muse, mutect2, varscan2
- CDH10 | c.1553C>A p.P518H | Missense Mutation (SNP) | VAF 124/493 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52602140; called by muse, mutect2, varscan2
- CDH23 | c.2422G>T p.G808W | Missense Mutation (SNP) | VAF 152/356 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54926982; called by muse, mutect2, varscan2
- CHD3 | c.5836G>T p.A1946S (on ENST00000330494 / NM_001005273.3; = p.A1912S on NM_005852.4) | Missense Mutation (SNP) | VAF 386/659 reads (59%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as COSV57872559; called by muse, mutect2, varscan2
- CHRM2 | c.926C>A p.S309Y | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV57770104; called by muse, mutect2, varscan2
- COL11A1 | c.3982C>A p.Q1328K | Missense Mutation (SNP) | VAF 195/244 reads (80%) | SIFT tolerated (0.85); PolyPhen benign (0.037); catalogued as rs750014974, COSV62175382, COSV62199216; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 280/719 reads (39%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.993); catalogued as rs761609779; called by muse, mutect2, varscan2
- CST7 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 21/320 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV65195995; called by muse, mutect2
- CTNNA2 | c.1906C>A p.L636I | Missense Mutation (SNP) | VAF 59/198 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.377); catalogued as COSV58173260; called by muse, mutect2, varscan2
- CUBN | c.2326G>T p.G776* | Nonsense Mutation (SNP) | VAF 72/212 reads (34%) | catalogued as COSV100912815; called by muse, mutect2, varscan2
- DDIAS | c.367G>T p.G123* | Nonsense Mutation (SNP) | VAF 166/200 reads (83%) | catalogued as COSV100231072; called by muse, mutect2, varscan2
- DENND2A | c.3029A>T p.*1010Lext*91 | Nonstop Mutation (SNP) | VAF 26/146 reads (18%) | catalogued as rs1232406686; called by muse, mutect2, varscan2
- DHX16 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 168/256 reads (66%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV64580460; called by muse, mutect2, varscan2
- DMD | c.8740G>T p.E2914* | Nonsense Mutation (SNP) | VAF 206/487 reads (42%) | catalogued as CM150622, COSV100627161; called by muse, mutect2, varscan2
- DNAH8 | c.6046C>G p.H2016D | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59429708; called by muse, mutect2, varscan2
- DOCK4 | c.5438G>T p.G1813V | Missense Mutation (SNP) | VAF 126/243 reads (52%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.026); catalogued as COSV101447881; called by muse, mutect2, varscan2
- DQX1 | c.1016T>A p.V339D | Missense Mutation (SNP) | VAF 241/403 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV101099113; called by muse, mutect2, varscan2
- DSC1 | c.2474C>A p.P825H | Missense Mutation (SNP) | VAF 276/448 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99938289; called by muse, mutect2
- DTNA | c.1033A>G p.M345V | Missense Mutation (SNP) | VAF 266/1068 reads (25%) | SIFT tolerated (0.56); PolyPhen benign (0.028); catalogued as rs374704854, COSV99312746; called by muse, mutect2, varscan2
- ELK1 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 272/720 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.005); catalogued as rs766008788, COSV55952051; called by muse, mutect2, varscan2
- EMD | c.70G>T p.G24W | Missense Mutation (SNP) | VAF 204/545 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63962577; called by muse, mutect2, varscan2
- EPHA6 | c.2116T>C p.Y706H (on ENST00000389672 / NM_001080448.3; = p.Y98H on NM_173655.4) | Missense Mutation (SNP) | VAF 49/136 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1160751918; called by muse, mutect2, varscan2
- ERVV-1 | c.425G>T p.G142V | Missense Mutation (SNP) | VAF 38/45 reads (84%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as rs1400900382; called by mutect2, varscan2
- EXOSC10 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 118/130 reads (91%) | SIFT tolerated (0.14); PolyPhen benign (0.276); catalogued as COSV99061300; called by muse, mutect2, varscan2
- F9 | c.1261G>T p.G421W | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV54379247; called by muse, mutect2, varscan2
- F9 | c.1262G>T p.G421V | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV54382386; called by muse, mutect2, varscan2
- FAM47A | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 182/384 reads (47%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.835); catalogued as COSV100650032; called by muse, mutect2, varscan2
- FMNL3 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 34/84 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1244619926, COSV53298936, COSV53305880; called by muse, mutect2, varscan2
- FOXB2 | c.812C>A p.A271D | Missense Mutation (SNP) | VAF 356/389 reads (92%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65022903; called by muse, mutect2, varscan2
- GDNF | c.250del p.A84Qfs*37 | Frame Shift Del (DEL) | VAF 49/175 reads (28%) | catalogued as COSV58479294; called by mutect2, pindel, varscan2
- GLOD5 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 54/127 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs1557017311, COSV57488756, COSV57490344; called by muse, mutect2, varscan2
- GMCL1 | c.846G>A p.W282* | Nonsense Mutation (SNP) | VAF 84/141 reads (60%) | catalogued as COSV57000380; called by muse, mutect2, varscan2
- GNAS | c.1613C>A p.A538D | Missense Mutation (SNP) | VAF 649/733 reads (89%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV104401843; called by muse, mutect2, varscan2
- GPR148 | c.133C>A p.P45T | Missense Mutation (SNP) | VAF 23/103 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.151); catalogued as COSV59307807; called by muse, mutect2, varscan2
- GPR174 | c.804G>T p.R268S | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.12); PolyPhen benign (0.068); catalogued as COSV52134942; called by muse, mutect2, varscan2
- GPR45 | c.809T>A p.L270Q | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV51524784; called by muse, mutect2
- GRID1 | c.2284G>A p.G762S | Missense Mutation (SNP) | VAF 145/412 reads (35%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.524); catalogued as rs769403835, COSV60037244; called by muse, mutect2, varscan2
- GTPBP10 | c.700G>T p.V234F | Missense Mutation (SNP) | VAF 115/210 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1188943062; called by muse, mutect2, varscan2
- HDAC6 | c.74A>T p.Q25L | Missense Mutation (SNP) | VAF 88/277 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as COSV100491407; called by muse, mutect2, varscan2
- HDGFL2 | c.1946G>A p.R649K (on ENST00000616600 / NM_001001520.3; = p.R648K on NM_032631.4) | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT tolerated, low confidence (0.7); catalogued as rs1207255209, COSV56683316; called by muse, mutect2, varscan2
- HIBADH | c.649G>T p.A217S | Missense Mutation (SNP) | VAF 134/313 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.362); catalogued as rs1245896544; called by muse, mutect2, varscan2
- HOXB3 | c.164A>T p.Q55L | Missense Mutation (SNP) | VAF 224/897 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV100290669; called by muse, mutect2, varscan2
- IGKV1D-37 | c.328G>C p.G110R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs754019562; called by mutect2, varscan2
- ITGA2B | c.2468G>A p.G823E | Missense Mutation (SNP) | VAF 38/566 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1166506747, CM153666, COSV52231778, COSV99288414; called by muse, mutect2
- KNDC1 | c.2806G>T p.G936C | Missense Mutation (SNP) | VAF 99/215 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs1023502252, COSV58835683; called by muse, mutect2, varscan2
- L1CAM | c.955G>T p.G319C | Missense Mutation (SNP) | VAF 107/238 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100649220; called by muse, mutect2, varscan2
- L1TD1 | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 87/249 reads (35%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as rs772595112; called by muse, mutect2, varscan2
- LAMC2 | c.3069+5A>G | Splice Region (SNP) | VAF 76/153 reads (50%) | catalogued as rs1262237378; called by muse, mutect2, varscan2
- LRRTM4 | c.1029G>T p.K343N | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.981); catalogued as COSV69138961; called by muse, mutect2, varscan2
- MAOA | c.815C>T p.A272V | Missense Mutation (SNP) | VAF 127/348 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1452282305, COSV58643922; called by muse, mutect2, varscan2
- MCM9 | c.767G>A p.R256H | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs769154294, COSV60165109; called by muse, mutect2
- MDGA2 | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 95/145 reads (66%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as COSV62100690; called by muse, mutect2, varscan2
- MROH5 | c.1967G>A p.G656E | Missense Mutation (SNP) | VAF 37/438 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV71300470; called by muse, mutect2
- MUC19 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 55/377 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs755267270; called by muse, mutect2, varscan2
- MYH2 | c.4058A>G p.Y1353C | Missense Mutation (SNP) | VAF 285/998 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs1413745380, COSV99820826; called by muse, mutect2, varscan2
- MYO3B | c.3625C>T p.H1209Y | Missense Mutation (SNP) | VAF 75/146 reads (51%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs759727109; called by muse, mutect2, varscan2
- NBAS | c.6160G>A p.D2054N | Missense Mutation (SNP) | VAF 95/414 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.118); catalogued as COSV55713397; called by muse, mutect2, varscan2
- NCAN | c.3445G>A p.D1149N | Missense Mutation (SNP) | VAF 278/312 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53049175; called by muse, mutect2, varscan2
- NEK8 | c.1013C>T p.A338V | Missense Mutation (SNP) | VAF 21/191 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs760766665; called by muse, mutect2, varscan2
- NELL1 | c.2258C>A p.P753H | Missense Mutation (SNP) | VAF 22/449 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54297916; called by muse, mutect2
- NLGN4X | c.2006G>C p.R669P | Missense Mutation (SNP) | VAF 207/552 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV52008892; called by muse, mutect2, varscan2
- OCSTAMP | c.728G>A p.W243* | Nonsense Mutation (SNP) | VAF 203/231 reads (88%) | catalogued as rs1568897913; called by muse, mutect2, varscan2
- OR2W1 | c.391C>T p.H131Y | Missense Mutation (SNP) | VAF 52/197 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.959); catalogued as rs1406577905; called by muse, mutect2, varscan2
- OR4Q2 | c.389C>G p.P130R | Missense Mutation (SNP) | VAF 74/139 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs574701039, COSV73406239; called by muse, mutect2, varscan2
- PAX6 | c.107G>T p.G36V | Missense Mutation (SNP) | VAF 197/223 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM065370, CM081729; called by muse, mutect2, varscan2
- PHF20 | c.2459G>A p.R820K | Missense Mutation (SNP) | VAF 186/212 reads (88%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV100926495; called by muse, mutect2, varscan2
- PIGT | c.868-1G>A p.X290_splice | Splice Site (SNP) | VAF 12/139 reads (9%) | catalogued as COSV54127795; called by muse, mutect2
- PKHD1L1 | c.6781G>T p.V2261F | Missense Mutation (SNP) | VAF 118/204 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.374); catalogued as COSV65755557; called by muse, mutect2, varscan2
- PKLR | c.1013G>T p.G338V | Missense Mutation (SNP) | VAF 245/807 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61362497; called by muse, mutect2, varscan2
- PPP1R12B | c.115C>G p.R39G | Missense Mutation (SNP) | VAF 183/619 reads (30%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.018); catalogued as rs761491383; called by muse, mutect2, varscan2
- RB1 | c.764del p.R255Qfs*9 | Frame Shift Del (DEL) | VAF 149/273 reads (55%) | catalogued as COSV57325097; called by mutect2, pindel, varscan2
- RBM12B | c.1505G>T p.R502L | Missense Mutation (SNP) | VAF 98/298 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.018); catalogued as COSV67898481; called by muse, mutect2, varscan2
- RNASE1 | c.335G>A p.C112Y | Missense Mutation (SNP) | VAF 210/579 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1390933065; called by muse, mutect2, varscan2
- RTL3 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.033); catalogued as rs780612504, COSV58183541; called by muse, mutect2, varscan2
- SCRN3 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 75/261 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.028); catalogued as rs140532560; called by muse, mutect2, varscan2
- SEC62 | c.252-7C>T | Splice Region (SNP) | VAF 71/497 reads (14%) | catalogued as rs372449686; called by muse, mutect2, varscan2
- SECISBP2L | c.1205G>A p.G402E (on ENST00000559471 / NM_001193489.2; = p.G357E on NM_014701.4) | Missense Mutation (SNP) | VAF 43/53 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs1231994765, COSV55934286; called by muse, mutect2, varscan2
- SERTAD3 | c.158G>C p.R53P | Missense Mutation (SNP) | VAF 55/78 reads (71%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.797); catalogued as COSV59325612; called by muse, mutect2, varscan2
- SFPQ | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 158/914 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs1557815488; called by muse, mutect2, varscan2
- SH2D1A | c.96G>T p.R32S | Missense Mutation (SNP) | VAF 443/882 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CM1510942; called by muse, mutect2, varscan2
- SIX3 | c.804C>T p.N268= | Splice Region (SNP) | VAF 234/391 reads (60%) | catalogued as rs1558420188; called by muse, mutect2, varscan2
- SP140 | c.834del p.R279Efs*24 | Frame Shift Del (DEL) | VAF 70/326 reads (21%) | catalogued as COSV100614147; called by mutect2, pindel, varscan2
- SPRY2 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 30/588 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV65701236; called by muse, mutect2
- SRD5A1 | c.716G>T p.W239L | Missense Mutation (SNP) | VAF 109/180 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99075313; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2235G>T p.Q745H | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.837); catalogued as rs762985998; called by muse, mutect2
- TAF1 | c.2321C>A p.P774H (on ENST00000373790 / NM_138923.4; = p.P795H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 114/333 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52112560; called by muse, mutect2, varscan2
- TBX5 | c.1261C>A p.L421I | Missense Mutation (SNP) | VAF 319/1220 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.156); catalogued as COSV99051537; called by muse, mutect2, varscan2
- TFAP2D | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 151/323 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV99146316; called by muse, mutect2, varscan2
- TNN | c.2892G>T p.K964N | Missense Mutation (SNP) | VAF 145/548 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.948); catalogued as COSV53427942; called by muse, mutect2, varscan2
- TUBAL3 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as rs781815460, COSV66813840, COSV66813945; called by muse, mutect2, varscan2
- UBR3 | c.4940A>G p.Q1647R | Missense Mutation (SNP) | VAF 283/498 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); catalogued as rs757615038; called by muse, mutect2, varscan2
- USH2A | c.5929G>A p.E1977K | Missense Mutation (SNP) | VAF 104/455 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0.007); catalogued as rs1453112061; called by muse, mutect2, varscan2
- USP49 | c.1184A>G p.Y395C | Missense Mutation (SNP) | VAF 91/296 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs557155189; called by muse, mutect2, varscan2
- VCX | c.520C>A p.L174M | Missense Mutation (SNP) | VAF 160/664 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.729); catalogued as rs753145579; called by muse, varscan2
- WIF1 | c.409G>T p.G137C | Missense Mutation (SNP) | VAF 66/143 reads (46%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.973); catalogued as rs1388860567; called by muse, mutect2, varscan2
- XRN1 | c.2692G>C p.D898H | Missense Mutation (SNP) | VAF 75/302 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.101); catalogued as COSV53811679; called by muse, mutect2, varscan2
- ZDHHC20 | c.846A>G p.I282M | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs1171172490; called by muse, mutect2, varscan2
- ZEB1 | c.2111C>A p.S704Y | Missense Mutation (SNP) | VAF 97/212 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as rs1237800383; called by muse, mutect2, varscan2
- ZFHX4 | c.4409G>T p.W1470L | Missense Mutation (SNP) | VAF 222/412 reads (54%) | SIFT tolerated (1); PolyPhen possibly damaging (0.554); catalogued as rs772763644, COSV51500105; called by muse, mutect2, varscan2
- ZFYVE26 | c.7475A>C p.Q2492P | Missense Mutation (SNP) | VAF 23/486 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.921); catalogued as rs1427923880; called by muse, mutect2
- ZIC1 | c.274G>A p.A92T | Missense Mutation (SNP) | VAF 49/671 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as rs372593091; called by muse, mutect2
- ZIC3 | c.844G>A p.V282I | Missense Mutation (SNP) | VAF 133/308 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.025); catalogued as rs1235557142; called by muse, mutect2, varscan2
- ZNF257 | c.1394del p.G465Afs*15 | Frame Shift Del (DEL) | VAF 128/229 reads (56%) | catalogued as COSV71306197; called by mutect2, pindel, varscan2
- ABCB5 | c.3439A>T p.T1147S (on ENST00000404938 / NM_001163941.2; = p.T702S on NM_178559.6) | Missense Mutation (SNP) | VAF 100/172 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCD1 | c.533A>G p.Q178R | Missense Mutation (SNP) | VAF 176/431 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ABCG1 | c.1496A>T p.Y499F | Missense Mutation (SNP) | VAF 172/205 reads (84%) | SIFT tolerated (0.05); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- ACAD11 | c.1689-6G>T | Splice Region (SNP) | VAF 26/69 reads (38%) | called by muse, mutect2, varscan2
- ACOT12 | c.533C>A p.T178K | Missense Mutation (SNP) | VAF 134/161 reads (83%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- ACTL9 | c.742del p.L248Wfs*3 | Frame Shift Del (DEL) | VAF 66/222 reads (30%) | called by mutect2, pindel, varscan2
- ADAMTS12 | c.3659T>A p.L1220Q | Missense Mutation (SNP) | VAF 115/358 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ADAMTS14 | c.2903G>A p.C968Y | Missense Mutation (SNP) | VAF 108/287 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADARB2 | c.1621T>A p.W541R | Missense Mutation (SNP) | VAF 245/644 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ALAS2 | c.391C>G p.H131D | Missense Mutation (SNP) | VAF 95/266 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- ANK2 | c.2818del p.A940Qfs*8 | Frame Shift Del (DEL) | VAF 345/551 reads (63%) | called by mutect2, pindel, varscan2
- ANKRD33B | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 101/307 reads (33%) | called by muse, mutect2, varscan2
- ANO8 | c.797G>C p.G266A | Missense Mutation (SNP) | VAF 205/241 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AQP12A | c.125T>C p.M42T | Missense Mutation (SNP) | VAF 354/1123 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- ARFGEF1 | c.2170G>T p.G724W | Missense Mutation (SNP) | VAF 20/388 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ARHGAP21 | c.3872dup p.N1291Kfs*2 | Frame Shift Ins (INS) | VAF 14/50 reads (28%) | called by mutect2, varscan2
- ATG7 | c.1409T>G p.V470G | Missense Mutation (SNP) | VAF 117/163 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- ATP1A2 | c.1999C>A p.L667M | Missense Mutation (SNP) | VAF 479/829 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ATP4A | c.2101T>C p.F701L | Missense Mutation (SNP) | VAF 60/398 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP6V1C2 | c.219G>T p.Q73H | Missense Mutation (SNP) | VAF 198/341 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- ATRX | c.7377G>A p.M2459I | Missense Mutation (SNP) | VAF 48/162 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- BBOF1 | c.202A>C p.K68Q | Missense Mutation (SNP) | VAF 45/63 reads (71%) | SIFT tolerated (0.43); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- BBS5 | c.137A>T p.D46V | Missense Mutation (SNP) | VAF 20/252 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2
- BBS9 | c.1294G>T p.V432L | Missense Mutation (SNP) | VAF 314/1106 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- BCORL1 | c.1015G>T p.A339S | Missense Mutation (SNP) | VAF 135/334 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- BICRA | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- BRWD3 | c.94C>A p.L32I | Missense Mutation (SNP) | VAF 181/525 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- C3orf85 | c.162G>T p.W54C | Missense Mutation (SNP) | VAF 113/477 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- CACNA1E | c.3399G>T p.M1133I | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- CCDC102B | c.802C>G p.Q268E | Missense Mutation (SNP) | VAF 94/569 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- CCDC22 | c.504G>T p.R168S | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCDC61 | c.339G>T p.Q113H | Missense Mutation (SNP) | VAF 85/98 reads (87%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CCDC88A | c.4324A>G p.S1442G | Missense Mutation (SNP) | VAF 151/532 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CD5L | c.528C>G p.C176W | Missense Mutation (SNP) | VAF 447/783 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CEACAM16 | c.225G>C p.E75D | Missense Mutation (SNP) | VAF 387/435 reads (89%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- CENPE | c.818G>C p.S273T | Missense Mutation (SNP) | VAF 52/72 reads (72%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.614); called by muse, mutect2, varscan2
- CENPL | c.235C>G p.P79A | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CHI3L1 | c.749C>A p.P250H | Missense Mutation (SNP) | VAF 317/529 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CHRND | c.52G>T p.G18C | Missense Mutation (SNP) | VAF 8/139 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- CIR1 | c.96A>G p.I32M | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CNOT1 | c.3748G>T p.V1250L | Missense Mutation (SNP) | VAF 62/84 reads (74%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- COG4 | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 388/471 reads (82%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); called by muse, mutect2, varscan2
- COL1A2 | c.1484C>T p.P495L | Missense Mutation (SNP) | VAF 393/724 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- COL26A1 | c.439G>C p.E147Q (on ENST00000313669 / NM_001278563.3; = p.E145Q on NM_133457.4) | Missense Mutation (SNP) | VAF 129/236 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- COL6A3 | c.4811dup p.N1604Kfs*61 | Frame Shift Ins (INS) | VAF 114/274 reads (42%) | called by pindel, varscan2
- COL6A5 | c.1771G>T p.G591W | Missense Mutation (SNP) | VAF 171/405 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COPG1 | c.2131G>T p.A711S | Missense Mutation (SNP) | VAF 202/548 reads (37%) | SIFT tolerated (0.8); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CSMD1 | c.6246C>A p.A2082= (on ENST00000520002; = p.A2081= on NM_033225.6) | Splice Region (SNP) | VAF 131/158 reads (83%) | called by muse, mutect2, varscan2
- CSMD2 | c.5380+2T>A p.X1794_splice | Splice Site (SNP) | VAF 252/782 reads (32%) | called by muse, mutect2, varscan2
- CSMD3 | c.4516G>C p.D1506H (on ENST00000297405 / NM_001363185.1; = p.D1402H on NM_052900.3) | Missense Mutation (SNP) | VAF 67/205 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CSMD3 | c.2077_2078delinsT p.G693Cfs*4 (on ENST00000297405 / NM_001363185.1; = p.G589Cfs*4 on NM_052900.3) | Frame Shift Del (DEL) | VAF 67/199 reads (34%) | called by pindel, varscan2*
- CTNNA2 | c.2059G>C p.V687L | Missense Mutation (SNP) | VAF 160/275 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- CUBN | c.2327G>T p.G776V | Missense Mutation (SNP) | VAF 71/210 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CUX2 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 154/260 reads (59%) | called by muse, mutect2, varscan2
- CYP26B1 | c.931C>A p.Q311K | Missense Mutation (SNP) | VAF 99/318 reads (31%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- DBX2 | c.573dup p.V192Cfs*4 | Frame Shift Ins (INS) | VAF 28/97 reads (29%) | called by mutect2, pindel, varscan2
- DCAF8L2 | c.1710C>A p.H570Q | Missense Mutation (SNP) | VAF 55/130 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.041); called by muse, mutect2, varscan2
- DCC | c.2054-2A>T p.X685_splice | Splice Site (SNP) | VAF 177/590 reads (30%) | called by muse, mutect2, varscan2
- DCDC1 | c.3052C>T p.Q1018* (on ENST00000597505 / NM_001367979.1; = p.Q125* on NM_020869.3) | Nonsense Mutation (SNP) | VAF 82/105 reads (78%) | called by muse, mutect2, varscan2
- DCDC2C | c.860A>G p.D287G | Missense Mutation (SNP) | VAF 17/216 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.075); called by muse, mutect2
- DDX60 | c.1081A>G p.T361A | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- DES | c.809T>C p.L270P | Missense Mutation (SNP) | VAF 58/960 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DES | c.1289-4A>T | Splice Region (SNP) | VAF 321/617 reads (52%) | called by muse, mutect2, varscan2
- DGAT2L6 | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 105/263 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DGKK | c.308C>A p.P103Q | Missense Mutation (SNP) | VAF 69/165 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- DHFR | c.107A>G p.Q36R | Missense Mutation (SNP) | VAF 209/242 reads (86%) | SIFT tolerated (0.44); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DIP2C | c.1935G>T p.Q645H | Missense Mutation (SNP) | VAF 85/186 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- DOCK2 | c.2226T>A p.Y742* | Nonsense Mutation (SNP) | VAF 104/128 reads (81%) | called by muse, mutect2, varscan2
- DOCK4 | c.5437G>T p.G1813W | Missense Mutation (SNP) | VAF 126/242 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- DRC3 | c.499C>A p.P167T | Missense Mutation (SNP) | VAF 111/304 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- DSP | c.5843G>T p.G1948V | Missense Mutation (SNP) | VAF 110/398 reads (28%) | SIFT tolerated, low confidence (0.13); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- EEF1D | c.189+5G>A | Splice Region (SNP) | VAF 156/233 reads (67%) | called by muse, mutect2, varscan2
- EFNB1 | c.817A>T p.T273S | Missense Mutation (SNP) | VAF 81/212 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- EGFL6 | c.562A>G p.N188D | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ELP1 | c.3632G>T p.S1211I | Missense Mutation (SNP) | VAF 369/442 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- EML6 | c.601C>T p.L201F | Missense Mutation (SNP) | VAF 205/406 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ENTPD1 | c.465C>A p.S155R | Missense Mutation (SNP) | VAF 153/377 reads (41%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- EPHA3 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- EPHA4 | c.1298C>T p.T433I | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); called by muse, mutect2, varscan2
- EPHA6 | c.2055C>A p.N685K (on ENST00000389672 / NM_001080448.3; = p.N77K on NM_173655.4) | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0); called by muse, mutect2, varscan2
- ESCO1 | c.104T>C p.L35P | Missense Mutation (SNP) | VAF 126/328 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EXOC3 | c.1849T>C p.F617L | Missense Mutation (SNP) | VAF 539/885 reads (61%) | SIFT tolerated (0.29); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- FAM3A | c.622A>C p.N208H | Missense Mutation (SNP) | VAF 121/372 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM47C | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 114/243 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- FANCM | c.1156C>G p.L386V | Missense Mutation (SNP) | VAF 4/71 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.096); called by muse, mutect2
- FAT2 | c.3696C>G p.I1232M | Missense Mutation (SNP) | VAF 151/181 reads (83%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- FAT3 | c.6999C>A p.S2333R | Missense Mutation (SNP) | VAF 189/226 reads (84%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- FBXL7 | c.1363G>T p.D455Y | Missense Mutation (SNP) | VAF 586/972 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- FCRLA | c.860C>A p.S287Y (on ENST00000367959; = p.S264Y on NM_032738.4) | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- FER1L5 | c.548dup p.N183Kfs*28 | Frame Shift Ins (INS) | VAF 197/471 reads (42%) | called by mutect2, pindel, varscan2
- FRMPD4 | c.3526C>G p.H1176D | Missense Mutation (SNP) | VAF 88/262 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- FRY | c.1397G>T p.R466L | Missense Mutation (SNP) | VAF 111/157 reads (71%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- G6PC2 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 73/638 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- G6PD | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- G6PD | c.121G>T p.G41C | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GCGR | c.215C>A p.P72H | Missense Mutation (SNP) | VAF 275/879 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- GCM2 | c.125C>G p.P42R | Missense Mutation (SNP) | VAF 80/1049 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GHRHR | c.172A>G p.T58A | Missense Mutation (SNP) | VAF 76/1064 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.186); called by muse, mutect2
- GIN1 | c.936G>A p.M312I | Missense Mutation (SNP) | VAF 107/302 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- GJA3 | c.344T>G p.L115R | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- GLDC | c.2606C>T p.P869L | Missense Mutation (SNP) | VAF 332/398 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- GLI3 | c.1812+1G>T p.X604_splice | Splice Site (SNP) | VAF 35/855 reads (4%) | called by muse, mutect2
- GOPC | c.1175G>T p.R392L | Missense Mutation (SNP) | VAF 50/176 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- GPNMB | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 90/155 reads (58%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GPR174 | c.803G>T p.R268M | Missense Mutation (SNP) | VAF 41/84 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- GPR4 | c.337G>T p.V113L | Missense Mutation (SNP) | VAF 139/157 reads (89%) | SIFT tolerated (0.51); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- GPRASP1 | c.2890G>A p.E964K | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- GPX5 | c.306C>A p.N102K | Missense Mutation (SNP) | VAF 146/503 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRM3 | c.1647T>A p.C549* | Nonsense Mutation (SNP) | VAF 291/522 reads (56%) | called by muse, mutect2, varscan2
- GSTM3 | c.49-6C>T | Splice Region (SNP) | VAF 134/199 reads (67%) | called by muse, mutect2, varscan2
- H1-1 | c.457C>G p.P153A | Missense Mutation (SNP) | VAF 447/767 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- HAL | c.1362C>G p.D454E | Missense Mutation (SNP) | VAF 264/717 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HCN4 | c.708C>A p.S236R | Missense Mutation (SNP) | VAF 53/491 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HEXD | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 289/777 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HNF1A | c.1108-7C>T | Splice Region (SNP) | VAF 25/354 reads (7%) | called by muse, mutect2
- HSPA6 | c.1042G>T p.V348L | Missense Mutation (SNP) | VAF 50/560 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); called by muse, mutect2
- HSPA6 | c.1384G>T p.E462* | Nonsense Mutation (SNP) | VAF 40/172 reads (23%) | called by muse, mutect2, varscan2
- IFFO1 | c.677G>T p.G226V | Missense Mutation (SNP) | VAF 461/2105 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IL1RAPL1 | c.319C>G p.P107A | Missense Mutation (SNP) | VAF 89/208 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ITGA1 | c.1358T>C p.I453T | Missense Mutation (SNP) | VAF 190/1184 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- ITIH6 | c.1030G>A p.V344I | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.68); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ITIH6 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 105/297 reads (35%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KCNK2 | c.1146G>T p.R382S (on ENST00000444842 / NM_001017425.3; = p.R367S on NM_014217.4) | Missense Mutation (SNP) | VAF 242/404 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KDM5A | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 536/869 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); called by muse, mutect2, varscan2
- KIDINS220 | c.339C>G p.Y113* | Nonsense Mutation (SNP) | VAF 181/362 reads (50%) | called by muse, mutect2, varscan2
- KIF17 | c.972C>A p.S324R | Missense Mutation (SNP) | VAF 585/662 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIRREL1 | c.359del p.P120Qfs*11 | Frame Shift Del (DEL) | VAF 37/136 reads (27%) | called by mutect2, pindel, varscan2
- KRT222 | c.35C>A p.A12E | Missense Mutation (SNP) | VAF 84/506 reads (17%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- KSR2 | c.92T>A p.I31K | Missense Mutation (SNP) | VAF 71/269 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- LAMA4 | c.2327C>A p.T776N (on ENST00000230538 / NM_001105206.3; = p.T769N on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 179/463 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LANCL3 | c.838C>A p.L280I | Missense Mutation (SNP) | VAF 182/535 reads (34%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- LARS1 | c.3370G>A p.G1124R (on ENST00000394434 / NM_020117.11; = p.G1097R on NM_016460.3) | Missense Mutation (SNP) | VAF 12/410 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- LCOR | c.1456A>T p.N486Y | Missense Mutation (SNP) | VAF 69/159 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- LEMD3 | c.2494G>T p.G832C | Missense Mutation (SNP) | VAF 131/326 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- LINGO2 | c.109C>A p.Q37K | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LLGL2 | c.1220C>A p.A407D | Missense Mutation (SNP) | VAF 412/757 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); called by muse, mutect2, varscan2
- LMO7 | c.1391C>T p.S464F (on ENST00000357063; = p.S194F on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 151/203 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- LRP2 | c.5347G>C p.V1783L | Missense Mutation (SNP) | VAF 126/202 reads (62%) | SIFT tolerated (0.24); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- LRP6 | c.4208A>T p.K1403M | Missense Mutation (SNP) | VAF 33/660 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.706); called by muse, mutect2
- LRP8 | c.1681G>T p.D561Y | Missense Mutation (SNP) | VAF 188/343 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- LRRC37B | c.1342G>T p.D448Y | Missense Mutation (SNP) | VAF 142/535 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- LRRC4 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 135/416 reads (32%) | called by muse, mutect2, varscan2
- LRRK2 | c.498del p.M167Cfs*30 | Frame Shift Del (DEL) | VAF 111/216 reads (51%) | called by mutect2, pindel, varscan2
- LVRN | c.1483C>A p.Q495K | Missense Mutation (SNP) | VAF 111/132 reads (84%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEB6B | c.40A>G p.K14E | Missense Mutation (SNP) | VAF 60/147 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MALRD1 | c.4213G>A p.V1405I | Missense Mutation (SNP) | VAF 70/249 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- MAP3K13 | c.1050G>T p.E350D | Missense Mutation (SNP) | VAF 196/353 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MARCHF6 | c.1175G>T p.W392L | Missense Mutation (SNP) | VAF 141/554 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- MARCO | c.1397C>A p.S466Y | Missense Mutation (SNP) | VAF 56/197 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- MCF2 | c.103C>G p.R35G | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MED13L | c.5424G>T p.K1808N | Missense Mutation (SNP) | VAF 54/898 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MEX3C | c.667G>T p.A223S | Missense Mutation (SNP) | VAF 453/1449 reads (31%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- MON2 | c.2315T>C p.L772P | Missense Mutation (SNP) | VAF 46/122 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC1 | c.2743G>A p.G915S | Missense Mutation (SNP) | VAF 215/536 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MTMR1 | c.984G>T p.M328I | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- MTMR1 | c.1928C>A p.A643D | Missense Mutation (SNP) | VAF 101/230 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- MUC16 | c.290C>G p.S97C | Missense Mutation (SNP) | VAF 127/148 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- MYLK | c.3000del p.E1001Rfs*3 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | called by mutect2, pindel, varscan2
- MYO5A | c.1675T>A p.Y559N | Missense Mutation (SNP) | VAF 68/220 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO9A | c.3974A>G p.E1325G | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- MYRFL | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 86/229 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- MYT1L | c.1274A>T p.D425V | Missense Mutation (SNP) | VAF 268/480 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NCAPG2 | c.1291A>T p.T431S | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NFYA | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 67/248 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- NHSL2 | c.122C>A p.A41D | Missense Mutation (SNP) | VAF 186/414 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NID2 | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 114/185 reads (62%) | SIFT tolerated (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- NWD2 | c.5024C>A p.P1675Q | Missense Mutation (SNP) | VAF 193/233 reads (83%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- OPN5 | c.755_756delinsT p.K252Mfs*2 | Frame Shift Del (DEL) | VAF 28/104 reads (27%) | called by pindel, varscan2*
- OR10D3 | c.227T>A p.V76E | Missense Mutation (SNP) | VAF 184/227 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- OR2T12 | c.285T>A p.C95* | Nonsense Mutation (SNP) | VAF 144/437 reads (33%) | called by muse, mutect2, varscan2
- OR4K2 | c.715A>G p.T239A | Missense Mutation (SNP) | VAF 70/337 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- OR5B21 | c.569C>A p.T190K | Missense Mutation (SNP) | VAF 282/332 reads (85%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR6C1 | c.212T>A p.F71Y | Missense Mutation (SNP) | VAF 57/148 reads (39%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PAK4 | c.467C>A p.P156Q | Missense Mutation (SNP) | VAF 119/182 reads (65%) | SIFT tolerated (0.15); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- PARP14 | c.5203A>G p.R1735G | Missense Mutation (SNP) | VAF 126/253 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- PCDH15 | c.3845C>A p.A1282D | Missense Mutation (SNP) | VAF 98/216 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- PCNX1 | c.5423C>T p.S1808F | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PDE2A | c.1978C>G p.H660D | Missense Mutation (SNP) | VAF 21/274 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDZD4 | c.1459C>A p.L487M | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- PEX5L | c.806C>A p.A269E | Missense Mutation (SNP) | VAF 93/386 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PGBD1 | c.1810G>T p.G604* | Nonsense Mutation (SNP) | VAF 92/417 reads (22%) | called by muse, mutect2, varscan2
- PIK3C2G | c.1601dup p.N534Kfs*49 (on ENST00000676171; = p.N534Kfs*15 on NM_004570.5) | Frame Shift Ins (INS) | VAF 112/212 reads (53%) | called by mutect2, pindel, varscan2
- PIK3C3 | c.87G>C p.K29N | Missense Mutation (SNP) | VAF 251/439 reads (57%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLRG1 | c.1317G>A p.W439* | Nonsense Mutation (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2
- POP7 | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 266/1086 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.401); called by muse, mutect2, varscan2
- POTED | c.1480C>A p.L494M | Missense Mutation (SNP) | VAF 79/105 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- POTEI | c.878A>T p.K293M | Missense Mutation (SNP) | VAF 156/636 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- POU3F3 | c.728G>T p.G243V | Missense Mutation (SNP) | VAF 65/102 reads (64%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPP1R7 | c.953A>G p.K318R | Missense Mutation (SNP) | VAF 263/436 reads (60%) | SIFT tolerated (0.35); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PRRT4 | c.1170G>T p.W390C | Missense Mutation (SNP) | VAF 276/919 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- PRSS1 | c.470A>C p.E157A | Missense Mutation (SNP) | VAF 299/532 reads (56%) | SIFT tolerated (0.76); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- PRTG | c.1150C>T p.Q384* | Nonsense Mutation (SNP) | VAF 132/160 reads (83%) | called by muse, mutect2, varscan2
- PSMA6 | c.427A>G p.I143V | Missense Mutation (SNP) | VAF 55/149 reads (37%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RAB11FIP1 | c.864G>T p.Q288H | Missense Mutation (SNP) | VAF 170/267 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RAB39B | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RABL3 | c.622T>C p.Y208H | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- RADX | c.277T>A p.Y93N | Missense Mutation (SNP) | VAF 194/562 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- RANBP2 | c.1733G>T p.W578L | Missense Mutation (SNP) | VAF 481/829 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RASA1 | c.310G>T p.G104C | Missense Mutation (SNP) | VAF 614/709 reads (87%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- RASSF8 | c.358A>T p.I120F | Missense Mutation (SNP) | VAF 82/364 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- RBL1 | c.2489A>T p.H830L | Missense Mutation (SNP) | VAF 70/81 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- RBMXL3 | c.1558G>T p.A520S | Missense Mutation (SNP) | VAF 115/224 reads (51%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- RFPL4A | c.424G>C p.G142R | Missense Mutation (SNP) | VAF 190/517 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- RGMB | c.848G>T p.R283L (on ENST00000513185 / NM_001366508.1; = p.R324L on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 191/222 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RGS21 | c.26G>T p.R9M | Missense Mutation (SNP) | VAF 291/510 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- RGS21 | c.244G>T p.A82S | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- RHOXF2 | c.396C>A p.N132K | Missense Mutation (SNP) | VAF 323/1093 reads (30%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- RIC8A | c.819-2A>T p.X273_splice | Splice Site (SNP) | VAF 71/77 reads (92%) | called by muse, mutect2, varscan2
- RIMS2 | c.1615A>T p.S539C (on ENST00000666250 / NM_001348490.2; = p.S347C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- RLIM | c.1510G>T p.G504C | Missense Mutation (SNP) | VAF 66/198 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- ROBO3 | c.3881T>G p.L1294R | Missense Mutation (SNP) | VAF 182/449 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- RPL24 | c.188A>C p.Q63P | Missense Mutation (SNP) | VAF 69/134 reads (51%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- RXFP1 | c.1798G>T p.G600* | Nonsense Mutation (SNP) | VAF 101/118 reads (86%) | called by muse, mutect2, varscan2
- SAMD15 | c.435_448delinsA p.T146Sfs*2 | Frame Shift Del (DEL) | VAF 48/103 reads (47%) | called by pindel, varscan2*
- SAMD7 | c.942T>G p.I314M | Missense Mutation (SNP) | VAF 68/397 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SASH1 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 22/381 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- SETBP1 | c.3455A>C p.H1152P | Missense Mutation (SNP) | VAF 1364/2214 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SETX | c.5867C>G p.A1956G | Missense Mutation (SNP) | VAF 11/333 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2
- SGSM2 | c.2752G>T p.D918Y (on ENST00000426855 / NM_001098509.2; = p.D963Y on NM_014853.3) | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- SHROOM4 | c.821C>A p.P274Q | Missense Mutation (SNP) | VAF 158/394 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIRPD | c.11C>G p.P4R | Missense Mutation (SNP) | VAF 67/111 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2, varscan2
- SLC16A1 | c.1035G>C p.M345I | Missense Mutation (SNP) | VAF 134/503 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC16A13 | c.149C>A p.A50E | Missense Mutation (SNP) | VAF 244/947 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- SLC36A2 | c.1082C>A p.P361H | Missense Mutation (SNP) | VAF 466/534 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- SLC4A8 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 82/275 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- SLC6A1 | c.1477T>C p.C493R | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT tolerated (0.36); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SLC9A6 | c.1954G>T p.D652Y | Missense Mutation (SNP) | VAF 61/154 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- SLITRK1 | c.823C>A p.P275T | Missense Mutation (SNP) | VAF 152/272 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLITRK3 | c.1486C>A p.Q496K | Missense Mutation (SNP) | VAF 306/829 reads (37%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.608); called by muse, mutect2, varscan2
- SMARCA1 | c.762G>A p.W254* | Nonsense Mutation (SNP) | VAF 53/124 reads (43%) | called by muse, mutect2, varscan2
- SMARCD2 | c.154G>T p.G52W | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SMG9 | c.572G>T p.C191F | Missense Mutation (SNP) | VAF 171/199 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- SPAG17 | c.1636C>G p.Q546E | Missense Mutation (SNP) | VAF 180/335 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- SPATA31A1 | c.3959C>T p.P1320L | Missense Mutation (SNP) | VAF 72/607 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- SPDYE6 | c.301G>A p.G101R | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- SPEF2 | c.5263A>G p.I1755V | Missense Mutation (SNP) | VAF 99/303 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPON1 | c.5G>T p.R2M | Missense Mutation (SNP) | VAF 163/187 reads (87%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SPRED3 | c.931C>A p.R311S | Missense Mutation (SNP) | VAF 72/477 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- STMND1 | c.446C>G p.P149R | Missense Mutation (SNP) | VAF 147/284 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STXBP5 | c.1497del p.D500Ifs*36 | Frame Shift Del (DEL) | VAF 147/332 reads (44%) | called by mutect2, pindel, varscan2
- SYNJ2BP | c.143A>G p.K48R | Missense Mutation (SNP) | VAF 71/85 reads (84%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- TAF1 | c.845C>A p.P282Q (on ENST00000373790 / NM_138923.4; = p.P303Q on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- TAF15 | c.1651G>A p.G551R (on ENST00000605844 / NM_139215.3; = p.G548R on NM_003487.4) | Missense Mutation (SNP) | VAF 23/320 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.348); called by muse, mutect2
- TARS1 | c.377T>C p.V126A | Missense Mutation (SNP) | VAF 317/1081 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- TENM3 | c.464T>A p.L155H | Missense Mutation (SNP) | VAF 148/169 reads (88%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- THAP1 | c.412A>G p.T138A | Missense Mutation (SNP) | VAF 269/578 reads (47%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- THOC2 | c.4397G>A p.R1466K | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- THOC2 | c.1237C>A p.Q413K | Missense Mutation (SNP) | VAF 44/101 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TINAG | c.253A>T p.K85* | Nonsense Mutation (SNP) | VAF 128/244 reads (52%) | called by muse, mutect2, varscan2
- TMPRSS15 | c.2020G>T p.E674* | Nonsense Mutation (SNP) | VAF 197/245 reads (80%) | called by muse, mutect2, varscan2
- TPD52L3 | c.220C>A p.Q74K | Missense Mutation (SNP) | VAF 333/386 reads (86%) | SIFT deleterious (0.02); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- TRAF1 | c.85del p.D29Tfs*37 | Frame Shift Del (DEL) | VAF 187/285 reads (66%) | called by mutect2, pindel, varscan2
- TRGJP | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 222/367 reads (60%) | PolyPhen benign (0.444); called by muse, mutect2, varscan2
- TRIM55 | c.1347A>T p.Q449H | Missense Mutation (SNP) | VAF 362/666 reads (54%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TRIP12 | c.4942G>T p.G1648C | Missense Mutation (SNP) | VAF 59/280 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TTN | c.91278C>A p.Y30426* (on ENST00000591111; = p.Y23002* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 133/552 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.69159A>T p.E23053D (on ENST00000591111; = p.E15629D on NM_003319.4) | Missense Mutation (SNP) | VAF 48/176 reads (27%) | PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TTN | c.62410G>T p.A20804S (on ENST00000591111; = p.A13380S on NM_003319.4) | Missense Mutation (SNP) | VAF 30/328 reads (9%) | PolyPhen benign (0.068); called by muse, mutect2
- UBQLN2 | c.1141C>A p.Q381K | Missense Mutation (SNP) | VAF 184/477 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- UHRF1 | c.1849A>T p.N617Y (on ENST00000612630 / NM_001290050.1; = p.N630Y on NM_013282.4) | Missense Mutation (SNP) | VAF 188/235 reads (80%) | SIFT deleterious (0.01); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- VWA3A | c.1894G>C p.A632P | Missense Mutation (SNP) | VAF 7/153 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.928); called by muse, mutect2
- VXN | c.408G>T p.M136I | Missense Mutation (SNP) | VAF 226/367 reads (62%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- WDR6 | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 7/192 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- WNK4 | c.2330C>G p.P777R | Missense Mutation (SNP) | VAF 200/492 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- WTIP | c.767G>C p.C256S | Missense Mutation (SNP) | VAF 136/370 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ZBED6 | c.566A>T p.K189M | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2
- ZGRF1 | c.158T>C p.L53P | Missense Mutation (SNP) | VAF 79/88 reads (90%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZMYM3 | c.3614C>A p.P1205H | Missense Mutation (SNP) | VAF 87/264 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF148 | c.1651A>G p.K551E | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ZNF208 | c.935C>A p.P312H | Missense Mutation (SNP) | VAF 93/121 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF267 | c.1570G>T p.V524L | Missense Mutation (SNP) | VAF 50/74 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ZNF571 | c.472G>T p.E158* | Nonsense Mutation (SNP) | VAF 65/119 reads (55%) | called by muse, mutect2, varscan2
- ZNF571 | c.471T>G p.H157Q | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF596 | c.235G>C p.G79R | Missense Mutation (SNP) | VAF 84/107 reads (79%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF610 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 131/150 reads (87%) | SIFT tolerated (0.52); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- ZNF726 | c.731A>T p.Y244F | Missense Mutation (SNP) | VAF 75/89 reads (84%) | SIFT tolerated (0.09); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- ZNF778 | c.71C>A p.T24K | Missense Mutation (SNP) | VAF 44/59 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- ABCA7 | c.1321T>C p.L441= | Silent (SNP) | VAF 89/694 reads (13%) | called by muse, mutect2, varscan2
- ACE | c.1275G>T p.A425= | Silent (SNP) | VAF 68/196 reads (35%) | called by muse, mutect2, varscan2
- ADAMTS7 | c.2574G>A p.E858= | Silent (SNP) | VAF 75/570 reads (13%) | called by muse, mutect2, varscan2
- AMBP | c.474G>A p.R158= | Silent (SNP) | VAF 17/236 reads (7%) | catalogued as COSV54323639; called by muse, mutect2
- AMFR | c.354C>G p.L118= | Silent (SNP) | VAF 83/98 reads (85%) | called by muse, mutect2, varscan2
- ARHGEF25 | c.564C>T p.A188= | Silent (SNP) | VAF 92/186 reads (49%) | called by muse, mutect2, varscan2
- ARHGEF40 | c.2538G>A p.E846= | Silent (SNP) | VAF 110/243 reads (45%) | called by muse, mutect2, varscan2
- ASB11 | c.381G>T p.V127= | Silent (SNP) | VAF 64/148 reads (43%) | called by muse, mutect2, varscan2
- ATF6 | c.1143G>C p.V381= | Silent (SNP) | VAF 50/227 reads (22%) | called by muse, mutect2, varscan2
- ATRX | c.4686C>A p.P1562= | Silent (SNP) | VAF 42/110 reads (38%) | called by muse, mutect2
- AVEN | c.105A>C p.V35= | Silent (SNP) | VAF 51/58 reads (88%) | called by muse, mutect2, varscan2
- BEND4 | c.921A>T p.S307= | Silent (SNP) | VAF 194/233 reads (83%) | called by muse, varscan2
- C1QTNF3 | c.636A>T p.L212= | Silent (SNP) | VAF 417/685 reads (61%) | called by muse, mutect2, varscan2
- CCDC43 | c.27G>T p.A9= | Silent (SNP) | VAF 189/652 reads (29%) | called by muse, mutect2, varscan2
- CCDC80 | c.2053C>A p.R685= | Silent (SNP) | VAF 42/71 reads (59%) | catalogued as rs762206182, COSV52817054; called by muse, mutect2, varscan2
- CCL28 | c.132A>G p.E44= | Silent (SNP) | VAF 148/404 reads (37%) | called by muse, mutect2, varscan2
- CD19 | c.1104C>A p.A368= | Silent (SNP) | VAF 179/200 reads (90%) | called by muse, mutect2, varscan2
- CDRT1 | c.1161A>G p.E387= | Silent (SNP) | VAF 137/274 reads (50%) | catalogued as rs752125685; called by muse, mutect2, varscan2
- CEL | c.297G>T p.G99= (on ENST00000673714; = p.G96= on NM_001807.6) | Silent (SNP) | VAF 46/468 reads (10%) | called by muse, mutect2
- CELF4 | c.1032C>A p.L344= | Silent (SNP) | VAF 86/600 reads (14%) | catalogued as COSV100612201, COSV58452619; called by muse, mutect2, varscan2
- CFAP100 | c.612C>T p.V204= | Silent (SNP) | VAF 112/410 reads (27%) | called by muse, mutect2, varscan2
- CNKSR2 | c.2016A>C p.A672= | Silent (SNP) | VAF 53/152 reads (35%) | called by muse, mutect2, varscan2
- COL8A1 | c.705C>A p.G235= | Silent (SNP) | VAF 49/157 reads (31%) | called by muse, mutect2, varscan2
- COPG1 | c.2130G>T p.V710= | Silent (SNP) | VAF 210/562 reads (37%) | called by muse, mutect2, varscan2
- CTC1 | c.2616G>A p.L872= | Silent (SNP) | VAF 56/131 reads (43%) | called by muse, mutect2, varscan2
- CTNNAL1 | c.483A>T p.R161= | Silent (SNP) | VAF 96/121 reads (79%) | called by muse, mutect2, varscan2
- CTPS2 | c.810G>A p.L270= | Silent (SNP) | VAF 56/186 reads (30%) | called by muse, mutect2, varscan2
- CYTH4 | c.759C>A p.L253= | Silent (SNP) | VAF 152/181 reads (84%) | called by muse, mutect2, varscan2
- DBX2 | c.399G>C p.A133= | Silent (SNP) | VAF 227/487 reads (47%) | catalogued as rs994950313; called by muse, mutect2, varscan2
- DCAF12L2 | c.198C>A p.A66= | Silent (SNP) | VAF 148/345 reads (43%) | called by muse, varscan2
- DCAF8L2 | c.69A>G p.P23= | Silent (SNP) | VAF 115/219 reads (53%) | called by muse, mutect2, varscan2
- DNAH9 | c.5565C>T p.T1855= | Silent (SNP) | VAF 181/277 reads (65%) | called by muse, mutect2, varscan2
- EPG5 | c.6714A>G p.L2238= | Silent (SNP) | VAF 244/817 reads (30%) | called by muse, mutect2, varscan2
- F8 | c.7014G>C p.L2338= | Silent (SNP) | VAF 97/265 reads (37%) | catalogued as COSV57706026; called by muse, mutect2, varscan2
- FAM229A | c.117G>T p.P39= | Silent (SNP) | VAF 591/990 reads (60%) | called by muse, mutect2, varscan2
- FLNC | c.921G>A p.V307= | Silent (SNP) | VAF 90/1078 reads (8%) | called by muse, mutect2
- FMR1 | c.735A>G p.R245= | Silent (SNP) | VAF 75/170 reads (44%) | called by muse, mutect2, varscan2
- GANAB | c.2436A>C p.R812= | Silent (SNP) | VAF 148/183 reads (81%) | called by muse, mutect2, varscan2
- GFOD1 | c.1098C>A p.T366= | Silent (SNP) | VAF 220/356 reads (62%) | catalogued as COSV64954588; called by muse, mutect2, varscan2
- GPAM | c.1608C>T p.A536= | Silent (SNP) | VAF 175/525 reads (33%) | called by muse, mutect2, varscan2
- GPR119 | c.828A>T p.P276= | Silent (SNP) | VAF 88/180 reads (49%) | called by muse, mutect2, varscan2
- GRIPAP1 | c.994T>C p.L332= | Silent (SNP) | VAF 99/261 reads (38%) | catalogued as rs1557064337; called by muse, mutect2, varscan2
- GRM1 | c.51C>T p.S17= | Silent (SNP) | VAF 456/755 reads (60%) | catalogued as COSV51389090; called by muse, mutect2, varscan2
- GUCY2C | c.15G>T p.L5= | Silent (SNP) | VAF 265/386 reads (69%) | called by muse, mutect2, varscan2
- GUCY2D | c.438G>A p.A146= | Silent (SNP) | VAF 430/951 reads (45%) | catalogued as rs765243245; called by muse, mutect2, varscan2
- HCFC2 | c.258A>T p.V86= | Silent (SNP) | VAF 166/296 reads (56%) | called by muse, varscan2
- HMGXB3 | c.2484C>T p.G828= (on ENST00000613459; = p.G582= on NM_014983.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 174/205 reads (85%) | called by muse, mutect2, varscan2
- IGLV4-60 | c.196C>A p.R66= | Silent (SNP) | VAF 121/135 reads (90%) | called by muse, mutect2, varscan2
- ITPR2 | c.7035C>A p.A2345= | Silent (SNP) | VAF 212/341 reads (62%) | called by muse, mutect2, varscan2
- KDM1B | c.15G>T p.R5= | Silent (SNP) | VAF 139/264 reads (53%) | catalogued as rs530646636; called by muse, mutect2, varscan2
- KDM7A | c.2244G>A p.T748= | Silent (SNP) | VAF 65/264 reads (25%) | catalogued as rs748787338; called by muse, mutect2, varscan2
- KIAA2026 | c.195C>A p.I65= | Silent (SNP) | VAF 88/97 reads (91%) | called by muse, mutect2, varscan2
- KLHL34 | c.894C>G p.V298= | Silent (SNP) | VAF 17/37 reads (46%) | called by muse, varscan2
- KRT82 | c.1446C>T p.V482= | Silent (SNP) | VAF 295/731 reads (40%) | catalogued as COSV99233460; called by muse, mutect2, varscan2
- L1CAM | c.738C>T p.T246= | Silent (SNP) | VAF 270/642 reads (42%) | called by muse, mutect2, varscan2
- LAMB1 | c.1062G>A p.T354= | Silent (SNP) | VAF 125/454 reads (28%) | catalogued as rs754665572; called by muse, mutect2, varscan2
- LAMC3 | c.1053C>G p.R351= | Silent (SNP) | VAF 704/774 reads (91%) | called by muse, mutect2, varscan2
- LCT | c.1896A>G p.A632= | Silent (SNP) | VAF 406/675 reads (60%) | called by muse, mutect2, varscan2
- LEXM | c.162C>T p.A54= | Silent (SNP) | VAF 230/672 reads (34%) | called by muse, mutect2, varscan2
- LINGO2 | c.108C>A p.A36= | Silent (SNP) | VAF 10/10 reads (100%) | catalogued as COSV58065483; called by mutect2, varscan2
- LIX1 | c.771T>A p.T257= | Silent (SNP) | VAF 263/321 reads (82%) | called by muse, mutect2, varscan2
- LRRC45 | c.267C>T p.R89= | Silent (SNP) | VAF 247/724 reads (34%) | called by muse, mutect2, varscan2
- LRRC7 | c.1128C>G p.P376= (on ENST00000651989 / NM_001370785.2; = p.P343= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 150/174 reads (86%) | catalogued as COSV50596970; called by muse, mutect2, varscan2
- LRRC8E | c.1365G>T p.G455= | Silent (SNP) | VAF 28/235 reads (12%) | called by muse, mutect2, varscan2
- MNX1 | c.783G>A p.K261= | Silent (SNP) | VAF 93/429 reads (22%) | called by muse, mutect2, varscan2
- MUC2 | c.969C>T p.N323= | Silent (SNP) | VAF 364/408 reads (89%) | called by muse, mutect2, varscan2
- MUC5B | c.4653C>G p.A1551= | Silent (SNP) | VAF 16/224 reads (7%) | called by muse, mutect2
- MYH13 | c.4605G>A p.K1535= | Silent (SNP) | VAF 16/355 reads (5%) | called by muse, mutect2
- NAV2 | c.360C>T p.L120= | Silent (SNP) | VAF 190/264 reads (72%) | catalogued as rs907667470; called by muse, mutect2
- NID2 | c.1212G>T p.L404= | Silent (SNP) | VAF 117/189 reads (62%) | called by muse, mutect2, varscan2
- OR10K2 | c.261C>T p.S87= | Silent (SNP) | VAF 24/664 reads (4%) | called by muse, mutect2
- OR13D1 | c.150C>A p.S50= | Silent (SNP) | VAF 14/169 reads (8%) | called by muse, mutect2
- OR2A1 | c.387C>A p.L129= | Silent (SNP) | VAF 76/492 reads (15%) | called by mutect2, varscan2
- OR4N2 | c.150G>A p.K50= | Silent (SNP) | VAF 59/213 reads (28%) | catalogued as COSV60049877; called by muse, mutect2, varscan2
- OR51T1 | c.861T>A p.P287= | Silent (SNP) | VAF 220/259 reads (85%) | called by muse, mutect2, varscan2
- OTOF | c.402G>A p.L134= | Silent (SNP) | VAF 149/641 reads (23%) | catalogued as rs767664276; called by muse, mutect2, varscan2
- PAH | c.231T>C p.Y77= | Silent (SNP) | VAF 98/418 reads (23%) | catalogued as rs62507332, CM981430; called by muse, mutect2, varscan2
- PCDH9 | c.2151A>T p.I717= | Silent (SNP) | VAF 29/433 reads (7%) | called by muse, mutect2
- PHF8 | c.936G>T p.L312= (on ENST00000357988 / NM_001184896.1; = p.L276= on NM_015107.3) | Silent (SNP) | VAF 107/275 reads (39%) | catalogued as COSV57681546; called by muse, mutect2, varscan2
- PPP1R3A | c.2772A>T p.S924= | Silent (SNP) | VAF 18/226 reads (8%) | called by muse, mutect2
- PROKR2 | c.156C>T p.A52= | Silent (SNP) | VAF 487/812 reads (60%) | catalogued as rs775513724; called by muse, mutect2, varscan2
- PRPF3 | c.57G>A p.V19= | Silent (SNP) | VAF 109/619 reads (18%) | catalogued as COSV61395715; called by muse, mutect2, varscan2
- PRR14 | c.282A>T p.P94= | Silent (SNP) | VAF 299/326 reads (92%) | called by muse, mutect2, varscan2
- PTBP1 | c.951G>T p.A317= (on ENST00000349038 / NM_031991.4; = p.A343= on NM_002819.5) | Silent (SNP) | VAF 334/357 reads (94%) | called by muse, mutect2, varscan2
- RAB3GAP1 | c.2337C>T p.H779= | Silent (SNP) | VAF 131/537 reads (24%) | called by muse, mutect2, varscan2
- RAI2 | c.486C>G p.P162= | Silent (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- RAVER2 | c.178C>A p.R60= | Silent (SNP) | VAF 413/891 reads (46%) | catalogued as COSV53805282; called by muse, mutect2, varscan2
- REN | c.564C>T p.A188= | Silent (SNP) | VAF 93/308 reads (30%) | catalogued as rs777368574, COSV65817925; called by muse, mutect2, varscan2
- RYR1 | c.4777C>A p.R1593= | Silent (SNP) | VAF 1432/2297 reads (62%) | catalogued as COSV62092457; called by muse, mutect2, varscan2
- RYR2 | c.1453C>A p.R485= | Silent (SNP) | VAF 183/352 reads (52%) | catalogued as rs766420655, COSV63718535; called by muse, mutect2, varscan2
- RYR2 | c.13500C>T p.Y4500= | Silent (SNP) | VAF 76/304 reads (25%) | called by muse, mutect2, varscan2
- SCARA3 | c.378G>T p.G126= | Silent (SNP) | VAF 102/112 reads (91%) | catalogued as COSV100106730; called by muse, mutect2, varscan2
- SCN8A | c.3540A>G p.L1180= | Silent (SNP) | VAF 65/138 reads (47%) | called by muse, mutect2, varscan2
- SGCD | c.588C>A p.T196= (on ENST00000435422 / NM_001128209.2; = p.T197= on NM_000337.5) | Silent (SNP) | VAF 85/111 reads (77%) | catalogued as rs1469091652; called by muse, mutect2, varscan2
- SH3KBP1 | c.1968C>T p.N656= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as rs761536120, COSV65646223; called by muse, mutect2, varscan2
- SLC18A2 | c.582C>A p.I194= | Silent (SNP) | VAF 102/268 reads (38%) | catalogued as COSV53689667; called by muse, mutect2, varscan2
- SLC27A6 | c.1086A>C p.A362= | Silent (SNP) | VAF 156/187 reads (83%) | called by muse, mutect2, varscan2
- SLC6A17 | c.2139T>C p.Y713= | Silent (SNP) | VAF 105/155 reads (68%) | catalogued as COSV58996808; called by muse, mutect2, varscan2
- STPG3 | c.318C>T p.P106= | Silent (SNP) | VAF 17/420 reads (4%) | called by muse, mutect2
- STRN3 | c.1785T>C p.S595= (on ENST00000357479 / NM_001083893.2; = p.S511= on NM_014574.4) | Silent (SNP) | VAF 84/207 reads (41%) | called by muse, mutect2, varscan2
- SYN1 | c.1842G>T p.G614= | Silent (SNP) | VAF 36/99 reads (36%) | called by muse, mutect2, varscan2
- TBL2 | c.61C>T p.L21= | Silent (SNP) | VAF 202/712 reads (28%) | called by muse, mutect2, varscan2
- TBX22 | c.327G>A p.G109= | Silent (SNP) | VAF 131/391 reads (34%) | called by muse, mutect2, varscan2
- TDRD5 | c.2727T>C p.N909= | Silent (SNP) | VAF 50/151 reads (33%) | catalogued as rs750083325; called by muse, mutect2, varscan2
- TLR5 | c.1203T>C p.F401= | Silent (SNP) | VAF 54/174 reads (31%) | called by muse, mutect2, varscan2
- TMEM190 | c.408G>A p.K136= | Silent (SNP) | VAF 6/141 reads (4%) | called by muse, mutect2
- TPCN2 | c.1558C>T p.L520= | Silent (SNP) | VAF 186/244 reads (76%) | called by muse, mutect2
- TPCN2 | c.1560G>T p.L520= | Silent (SNP) | VAF 190/248 reads (77%) | called by muse, mutect2
- TRH | c.352C>A p.R118= | Silent (SNP) | VAF 298/679 reads (44%) | called by muse, mutect2, varscan2
- TRIM68 | c.372A>G p.P124= | Silent (SNP) | VAF 163/194 reads (84%) | catalogued as COSV56167533; called by muse, mutect2, varscan2
- TRMT1 | c.726G>C p.L242= | Silent (SNP) | VAF 101/109 reads (93%) | called by muse, mutect2, varscan2
- TTL | c.1041C>T p.C347= | Silent (SNP) | VAF 206/344 reads (60%) | called by muse, mutect2, varscan2
- UGGT1 | c.3528T>C p.Y1176= | Silent (SNP) | VAF 96/164 reads (59%) | called by muse, mutect2, varscan2
- USP7 | c.2364A>T p.R788= | Silent (SNP) | VAF 16/460 reads (3%) | called by muse, mutect2
- VCX | c.183C>T p.A61= | Silent (SNP) | VAF 86/530 reads (16%) | catalogued as rs1193877704; called by muse, mutect2
- VCX2 | c.183C>T p.A61= | Silent (SNP) | VAF 18/101 reads (18%) | called by mutect2, varscan2
- WIZ | c.4503G>T p.S1501= (on ENST00000673675 / NM_001371589.1; = p.S406= on NM_021241.3) | Silent (SNP) | VAF 274/314 reads (87%) | catalogued as COSV54605289; called by muse, mutect2, varscan2
- WNK1 | c.2661G>C p.G887= | Silent (SNP) | VAF 96/384 reads (25%) | called by muse, mutect2, varscan2
- XCL2 | c.93C>A p.T31= | Silent (SNP) | VAF 80/132 reads (61%) | called by muse, mutect2, varscan2
- ZNF208 | c.936C>A p.P312= | Silent (SNP) | VAF 94/122 reads (77%) | called by muse, mutect2, varscan2
- ZPBP | c.717A>G p.L239= | Silent (SNP) | VAF 20/350 reads (6%) | catalogued as COSV50422296; called by muse, mutect2
- AC006486.1 | c.23-3058A>G | Intron (SNP) | VAF 253/290 reads (87%) | catalogued as rs1267086723; called by muse, mutect2, varscan2
- AC107023.1 | n.25+7094C>A | Intron (SNP) | VAF 58/242 reads (24%) | called by muse, mutect2, varscan2
- ACTR3BP2 | n.694T>G | RNA (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2, varscan2
- ADGRG6 | c.1069+116T>C | Intron (SNP) | VAF 40/72 reads (56%) | catalogued as rs147132251; called by muse, mutect2
- ADI1 | c.420+40G>A | Intron (SNP) | VAF 72/179 reads (40%) | catalogued as rs1301724826; called by muse, mutect2, varscan2
- ATP9B | chr18:79069373 G>A | 5'Flank (SNP) | VAF 92/154 reads (60%) | called by muse, varscan2
- BTNL10 | n.348C>G | RNA (SNP) | VAF 67/308 reads (22%) | called by muse, mutect2, varscan2
- C17orf49 | c.-21C>G | 5'UTR (SNP) | VAF 598/1030 reads (58%) | called by muse, mutect2, varscan2
- C1R | chr12:7092452 G>A | 5'Flank (SNP) | VAF 42/765 reads (5%) | called by muse, mutect2
- C1orf112 | chr1:169795127 G>A | 5'Flank (SNP) | VAF 151/600 reads (25%) | catalogued as rs1464542616; called by muse, mutect2, varscan2
- CD8A | c.*148T>C | 3'UTR (SNP) | VAF 179/603 reads (30%) | called by muse, mutect2, varscan2
- CDCA5 | c.46+46dup | Intron (INS) | VAF 440/697 reads (63%) | called by mutect2, pindel, varscan2
- CDH9 | c.999+49G>T | Intron (SNP) | VAF 202/377 reads (54%) | called by muse, mutect2, varscan2
- CEBPZ | c.-2C>G | 5'UTR (SNP) | VAF 134/235 reads (57%) | catalogued as rs761762549; called by muse, mutect2, varscan2
- CYYR1 | c.-104G>T | 5'UTR (SNP) | VAF 269/296 reads (91%) | catalogued as COSV100176531, COSV100176566; called by muse, mutect2, varscan2
- DENND5B | c.128-4510G>A | Intron (SNP) | VAF 38/183 reads (21%) | called by muse, mutect2, varscan2
- DEPTOR | c.122+20G>T | Intron (SNP) | VAF 183/666 reads (27%) | catalogued as COSV104376570; called by muse, mutect2, varscan2
- DUSP13 | c.*357del | 3'UTR (DEL) | VAF 87/223 reads (39%) | catalogued as COSV57813042; called by mutect2, pindel, varscan2
- EIF1AX | c.-12G>T | 5'UTR (SNP) | VAF 79/221 reads (36%) | catalogued as COSV65451041; called by muse, mutect2, varscan2
- EPB41L1 | c.-15+340A>T | Intron (SNP) | VAF 13/99 reads (13%) | called by muse, mutect2, varscan2
- EXD3 | c.-15G>A | 5'UTR (SNP) | VAF 49/427 reads (11%) | catalogued as rs751250693; called by muse, mutect2, varscan2
- FRMD8P1 | n.556G>A | RNA (SNP) | VAF 231/583 reads (40%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.*193C>G | 3'UTR (SNP) | VAF 51/59 reads (86%) | called by muse, mutect2, varscan2
- GPATCH8 | c.*1105G>A | 3'UTR (SNP) | VAF 100/201 reads (50%) | catalogued as rs772885894; called by muse, mutect2, varscan2
- GRHL3 | c.17+3523G>T | Intron (SNP) | VAF 121/154 reads (79%) | called by muse, mutect2, varscan2
- GUSBP10 | n.568C>A | RNA (SNP) | VAF 213/373 reads (57%) | catalogued as rs1451098920; called by muse, mutect2, varscan2
- HGSNAT | c.1013-1439G>T | Intron (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- HIBADH | c.-45C>T | 5'UTR (SNP) | VAF 73/253 reads (29%) | catalogued as rs202178618; called by muse, mutect2, varscan2
- HSP90AA4P | n.1888del | RNA (DEL) | VAF 71/117 reads (61%) | called by mutect2, pindel, varscan2
- HYOU1 | c.1807-73G>T | Intron (SNP) | VAF 130/148 reads (88%) | catalogued as rs781904994; called by muse, mutect2, varscan2
- IGHV4-4 | c.-10G>T | 5'UTR (SNP) | VAF 163/208 reads (78%) | called by muse, mutect2, varscan2
- KLF6 | c.*2516G>A | 3'UTR (SNP) | VAF 54/612 reads (9%) | called by muse, mutect2
- KNG1 | c.-27C>A | 5'UTR (SNP) | VAF 208/399 reads (52%) | called by muse, mutect2, varscan2
- LARP7 | c.1142+57G>T | Intron (SNP) | VAF 33/42 reads (79%) | called by muse, mutect2, varscan2
- LINC00303 | n.230C>A | RNA (SNP) | VAF 196/350 reads (56%) | called by muse, mutect2, varscan2
- LINC00479 | n.653G>C | RNA (SNP) | VAF 13/236 reads (6%) | called by muse, mutect2
- LINC01148 | n.572C>T | RNA (SNP) | VAF 15/21 reads (71%) | catalogued as rs1216205056; called by muse, mutect2, varscan2
- MAP3K1 | c.-17G>T | 5'UTR (SNP) | VAF 51/59 reads (86%) | called by muse, mutect2, varscan2
- MAP3K3 | c.779-23A>G | Intron (SNP) | VAF 284/482 reads (59%) | called by muse, mutect2, varscan2
- MED23 | c.*768G>T | 3'UTR (SNP) | VAF 65/116 reads (56%) | called by muse, mutect2, varscan2
- NEURL3 | c.514+60C>A | Intron (SNP) | VAF 51/196 reads (26%) | catalogued as rs1169328599; called by muse, mutect2, varscan2
- PCBP2 | c.375+470A>G | Intron (SNP) | VAF 100/259 reads (39%) | called by muse, mutect2, varscan2
- PHF8 | c.2237+32G>T | Intron (SNP) | VAF 167/366 reads (46%) | catalogued as COSV57679194, COSV57680232; called by muse, mutect2, varscan2
- PLEKHF1 | c.-17+95C>T | Intron (SNP) | VAF 126/390 reads (32%) | catalogued as rs528750632; called by muse, mutect2, varscan2
- PLSCR2 | c.-30G>C | 5'UTR (SNP) | VAF 45/206 reads (22%) | called by muse, mutect2, varscan2
- PPA1 | c.-14A>C | 5'UTR (SNP) | VAF 158/317 reads (50%) | called by muse, mutect2, varscan2
- PROC | c.-30C>G | 5'UTR (SNP) | VAF 123/420 reads (29%) | called by muse, mutect2, varscan2
- PRRT1 | c.*281G>C | 3'UTR (SNP) | VAF 60/102 reads (59%) | called by muse, mutect2, varscan2
- RCC1 | c.-228-93G>A | Intron (SNP) | VAF 30/332 reads (9%) | catalogued as rs1396107143; called by muse, mutect2
- SLC45A2 | c.1156+43G>T | Intron (SNP) | VAF 226/439 reads (51%) | catalogued as COSV99672211; called by muse, mutect2, varscan2
- STK10 | c.521-10del | Intron (DEL) | VAF 95/148 reads (64%) | called by mutect2, pindel, varscan2
- TBC1D3P1 | n.149G>T | RNA (SNP) | VAF 153/661 reads (23%) | called by muse, mutect2, varscan2
- TRAPPC12 | c.1165-175C>T | Intron (SNP) | VAF 93/354 reads (26%) | catalogued as rs1262271671; called by muse, mutect2, varscan2
- TTN | c.10360+3945G>C | Intron (SNP) | VAF 20/52 reads (38%) | called by muse, mutect2, varscan2
- TXLNA | c.*566A>G | 3'UTR (SNP) | VAF 413/671 reads (62%) | catalogued as rs747300006; called by muse, mutect2, varscan2
- UPRT | c.823+20G>T | Intron (SNP) | VAF 52/113 reads (46%) | called by muse, mutect2, varscan2
- USP4 | c.696-5801A>T | Intron (SNP) | VAF 37/49 reads (76%) | called by muse, mutect2, varscan2
- UTP25 | c.1668+21C>G | Intron (SNP) | VAF 49/223 reads (22%) | called by muse, mutect2, varscan2
- WASF4P | n.255G>A | RNA (SNP) | VAF 191/469 reads (41%) | called by muse, mutect2, varscan2
- WASF4P | n.1056C>A | RNA (SNP) | VAF 60/187 reads (32%) | called by muse, mutect2, varscan2
- XIAP | c.*1708G>T | 3'UTR (SNP) | VAF 43/152 reads (28%) | called by muse, mutect2
- XIAP | c.*5395A>G | 3'UTR (SNP) | VAF 88/197 reads (45%) | catalogued as rs1441546641; called by muse, mutect2, varscan2
- YEATS2 | c.3785-357C>G | Intron (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.701+6599C>A | Intron (SNP) | VAF 27/38 reads (71%) | called by muse, mutect2, varscan2
- ZNF219 | chr14:21098847 A>T | 5'Flank (SNP) | VAF 67/154 reads (44%) | catalogued as rs563448693; called by muse, mutect2, varscan2
- ZNF268 | c.*6377G>T | 3'UTR (SNP) | VAF 135/531 reads (25%) | called by muse, mutect2, varscan2
- ZNF398 | c.-44C>T | 5'UTR (SNP) | VAF 45/157 reads (29%) | called by muse, mutect2, varscan2
- ZNF415 | c.136+587A>T | Intron (SNP) | VAF 191/229 reads (83%) | called by muse, mutect2, varscan2
